Somatic mutation profile of tumor specimen HCM-CSHL-0857-C19-06A (aliquot HCM-CSHL-0857-C19-06A-11D-A881-36) from HCMI case HCM-CSHL-0857-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,244 days).
Specimen HCM-CSHL-0857-C19-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a44974-c3fe-4cc4-8788-a6fbda2bff79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0857-C19-11A (Solid Tissue Normal), aliquot HCM-CSHL-0857-C19-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8567324-b014-4dc1-a93c-45a4e3523041

The open-access MAF lists 169 somatic variants for this specimen: 123 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 43, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 2, Splice Region 2, In Frame Del 2, Splice Site 2, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 88/237 reads (37%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 90/308 reads (29%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CYP17A1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 101/452 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894149, CM024701, COSV64005060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.398T>G p.M133R | Missense Mutation (SNP) | VAF 215/268 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.129); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, mutect2, varscan2
- ABCA12 | c.6424C>T p.R2142C (on ENST00000272895 / NM_173076.3; = p.R1824C on NM_015657.3) | Missense Mutation (SNP) | VAF 85/219 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); catalogued as rs758122196, COSV55948948; called by muse, mutect2, varscan2
- ACSM4 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 97/285 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1436222747; called by muse, mutect2, varscan2
- BNC2 | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 100/386 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV66150559; called by mutect2, varscan2
- BTBD11 | c.1943C>A p.T648N (on ENST00000280758 / NM_001018072.2; = p.T185N on NM_001017523.2) | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.602); catalogued as rs1222826555; called by muse, mutect2
- BTBD3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 567/833 reads (68%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs930540638, COSV54778752; called by muse, mutect2, varscan2
- CACNA1E | c.5237G>A p.R1746H | Missense Mutation (SNP) | VAF 71/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62391346; called by muse, mutect2, varscan2
- CALHM1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 217/394 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs202160393, COSV53294861; called by muse, varscan2
- CALHM6 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 27/833 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1355970784; called by muse, mutect2
- DLGAP2 | c.2314A>T p.S772C | Missense Mutation (SNP) | VAF 159/225 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV70099426; called by muse, mutect2, varscan2
- DNAH10 | c.10975C>G p.R3659G (on ENST00000409039; = p.R3598G on NM_207437.3) | Missense Mutation (SNP) | VAF 28/778 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101293032; called by muse, mutect2
- ELAVL3 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100820737; called by muse, mutect2, varscan2
- FABP4 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1450734289; called by muse, mutect2, varscan2
- FCGR3A | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 81/408 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1031388823, COSV100914641; called by muse, mutect2, varscan2
- FILIP1L | c.3259C>A p.L1087M (on ENST00000354552 / NM_182909.3; = p.L847M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs772465470; called by muse, mutect2, varscan2
- GRIN2A | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 233/1038 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs143833346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 242/552 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs200903876; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HERC2 | c.10854C>A p.H3618Q | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55356431; called by muse, mutect2
- HTR1A | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 199/478 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs764663330; called by muse, mutect2, varscan2
- ITGB8 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 257/660 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1228157455; called by muse, mutect2, varscan2
- KCNH5 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs533454331, COSV59757653, COSV59765420; called by muse, mutect2, varscan2
- KYAT3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs759620693, COSV53099540; called by muse, mutect2, varscan2
- LAIR1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 239/858 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs201618231, COSV57305754, COSV57307996; called by muse, mutect2, varscan2
- LILRA1 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV99070432; called by muse, mutect2, varscan2
- LY6K | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 190/1022 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV99456542; called by muse, mutect2, varscan2
- MRPL55 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs760580888; called by muse, mutect2, varscan2
- OPCML | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs749718972, COSV59402476; called by muse, mutect2, varscan2
- OPLAH | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 619/834 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs367992509; called by muse, mutect2, varscan2
- PCDHA13 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs199942713, COSV56482025; called by muse, mutect2, varscan2
- PLEKHA2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 133/557 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs758412940; called by muse, mutect2, varscan2
- POTEM | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as rs531611167, COSV101304489; called by mutect2, varscan2
- PRG4 | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 150/574 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs777305605; called by muse, mutect2, varscan2
- RASSF2 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV101040888; called by muse, mutect2, varscan2
- RBFOX1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 80/372 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60954857, COSV60986955; called by muse, mutect2, varscan2
- RBM12 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 82/467 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467748; called by muse, mutect2, varscan2
- RYR2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 131/266 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs368974917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 119/406 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs770463034, COSV56572969; called by muse, mutect2, varscan2
- SORCS1 | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 140/265 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs773862245, COSV53899675; called by muse, mutect2, varscan2
- SPTLC3 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 75/488 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs756668458; called by muse, mutect2, varscan2
- STIP1 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as COSV59438877; called by muse, mutect2, varscan2
- SYF2 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs545105070; called by muse, mutect2, varscan2
- TMEM132C | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 250/461 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs985061554, COSV59424989; called by muse, mutect2, varscan2
- TMEM231 | c.520G>A p.G174R (on ENST00000258173 / NM_001077418.3; = p.G203R on NM_001077416.2) | Missense Mutation (SNP) | VAF 215/440 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763194213, COSV50738405; called by muse, mutect2, varscan2
- TRMT1L | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 119/453 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV62259414; called by muse, mutect2, varscan2
- ZCCHC2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV54041842; called by muse, mutect2, varscan2
- ZNF716 | c.391A>T p.S131C | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV70779306, COSV70780167; called by mutect2, varscan2
- A2M | c.1193C>A p.T398N | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADCY1 | c.2257del p.M753* | Frame Shift Del (DEL) | VAF 230/899 reads (26%) | called by pindel, varscan2
- ADGRL2 | c.3923T>C p.L1308S (on ENST00000370717 / NM_001366005.1; = p.L1252S on NM_012302.4) | Missense Mutation (SNP) | VAF 177/228 reads (78%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRL4 | c.775_776insG p.F259Cfs*3 | Frame Shift Ins (INS) | VAF 12/23 reads (52%) | called by mutect2, pindel, varscan2
- AGXT | c.1071G>A p.K357= | Splice Region (SNP) | VAF 172/382 reads (45%) | called by muse, mutect2, varscan2
- ANKS1B | c.2068A>T p.R690* | Nonsense Mutation (SNP) | VAF 167/496 reads (34%) | called by muse, mutect2, varscan2
- APC | c.7855G>A p.E2619K | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ASAH2 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCHE | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); called by mutect2, varscan2
- BCOR | c.4537G>A p.V1513M (on ENST00000378444 / NM_001123385.2; = p.V1479M on NM_017745.6) | Missense Mutation (SNP) | VAF 168/456 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH17 | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 84/540 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC16A | c.344-1G>C p.X115_splice | Splice Site (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2
- CSTF1 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 130/1098 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CUL1 | c.1948-1G>A p.X650_splice | Splice Site (SNP) | VAF 70/259 reads (27%) | called by muse, mutect2, varscan2
- CYP7A1 | c.711A>T p.K237N | Missense Mutation (SNP) | VAF 128/740 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKH | c.477A>T p.R159S | Missense Mutation (SNP) | VAF 161/268 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1158_1193del p.P387_I398del | In Frame Del (DEL) | VAF 26/132 reads (20%) | called by mutect2, pindel, varscan2
- EPAS1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 98/604 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.3545G>T p.W1182L | Missense Mutation (SNP) | VAF 183/318 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.188); called by muse, varscan2
- FAT1 | c.4542_4543del p.T1516Ffs*2 | Frame Shift Del (DEL) | VAF 104/510 reads (20%) | called by pindel, varscan2
- FOXM1 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 120/313 reads (38%) | called by muse, mutect2, varscan2
- FOXRED1 | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 117/575 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GABRE | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GCLM | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- HCN1 | c.2474C>T p.T825M | Missense Mutation (SNP) | VAF 176/451 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQGAP2 | c.1177C>A p.Q393K | Missense Mutation (SNP) | VAF 123/331 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITGAM | c.2643T>G p.N881K (on ENST00000648685 / NM_001145808.2; = p.N880K on NM_000632.4) | Missense Mutation (SNP) | VAF 66/302 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by mutect2, varscan2
- KBTBD7 | c.1421T>A p.F474Y | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KIF13B | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 75/105 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIRREL2 | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT27 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- LCOR | c.2410A>T p.K804* | Nonsense Mutation (SNP) | VAF 80/283 reads (28%) | called by muse, mutect2, varscan2
- LRBA | c.6521_6526del p.K2174_V2176delinsM | In Frame Del (DEL) | VAF 29/136 reads (21%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 173/379 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARK4 | c.968C>G p.T323R | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MNT | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 210/536 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MOCOS | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTARC1 | c.593T>C p.L198S | Missense Mutation (SNP) | VAF 96/237 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYO7A | c.5585A>C p.K1862T | Missense Mutation (SNP) | VAF 166/2828 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2
- NAV3 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 106/374 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBR1 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFKB2 | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 282/467 reads (60%) | SIFT tolerated (0.83); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NTM | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 75/623 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4C16 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR7G1 | c.776A>C p.Y259S | Missense Mutation (SNP) | VAF 58/254 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- PCDHA11 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 207/567 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PCDHAC1 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 159/413 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIEZO1 | c.5336C>T p.T1779I | Missense Mutation (SNP) | VAF 152/817 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- POTEG | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 194/2052 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2
- PPP4R3A | c.81_115del p.S28Pfs*6 | Frame Shift Del (DEL) | VAF 86/476 reads (18%) | called by mutect2, varscan2
- PRRC2B | c.3691A>G p.S1231G | Missense Mutation (SNP) | VAF 141/546 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RMDN1 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 70/426 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RREB1 | c.3310T>A p.L1104I | Missense Mutation (SNP) | VAF 189/661 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR3 | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- SAMD14 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 211/826 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SCAP | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 114/450 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SCTR | c.924T>A p.I308= | Splice Region (SNP) | VAF 54/261 reads (21%) | called by muse, mutect2, varscan2
- SPATA3 | c.326A>T p.K109M | Missense Mutation (SNP) | VAF 27/1154 reads (2%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2
- STAM | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by mutect2, varscan2
- TBCK | c.2339T>C p.F780S (on ENST00000273980 / NM_001163436.4; = p.F717S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/413 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS9 | c.1477A>C p.T493P (on ENST00000648592; = p.T459P on NM_182973.2) | Missense Mutation (SNP) | VAF 119/566 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNN | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- TPBGL | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 134/905 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM47 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 207/852 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UGCG | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.10624G>T p.E3542* | Nonsense Mutation (SNP) | VAF 64/152 reads (42%) | called by mutect2, varscan2
- WDR87 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 130/382 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ZCCHC14 | c.1658A>C p.K553T (on ENST00000268616; = p.K690T on NM_015144.3) | Missense Mutation (SNP) | VAF 149/966 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZCCHC2 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZIM2 | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 82/302 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF292 | c.3498_3499insG p.F1167Vfs*54 | Frame Shift Ins (INS) | VAF 115/411 reads (28%) | called by mutect2, pindel, varscan2
- ZNF587 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 76/296 reads (26%) | called by muse, varscan2
- ZNF804A | c.2003G>C p.S668T | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF98 | c.1316G>T p.C439F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ABCA7 | c.1917G>A p.T639= | Silent (SNP) | VAF 415/711 reads (58%) | catalogued as rs746473132; called by muse, mutect2, varscan2
- ABCC12 | c.1656C>A p.I552= | Silent (SNP) | VAF 103/722 reads (14%) | called by muse, mutect2, varscan2
- AHDC1 | c.1281C>T p.A427= | Silent (SNP) | VAF 460/799 reads (58%) | catalogued as rs753828677; called by muse, mutect2, varscan2
- ASXL2 | c.3069C>T p.T1023= | Silent (SNP) | VAF 107/587 reads (18%) | called by muse, mutect2, varscan2
- B3GNT7 | c.543C>A p.S181= | Silent (SNP) | VAF 519/1184 reads (44%) | called by muse, mutect2, varscan2
- BTBD11 | c.1944C>A p.T648= (on ENST00000280758 / NM_001018072.2; = p.T185= on NM_001017523.2) | Silent (SNP) | VAF 15/403 reads (4%) | called by muse, mutect2
- CELSR1 | c.8955G>A p.R2985= | Silent (SNP) | VAF 204/494 reads (41%) | called by muse, varscan2
- CFAP92 | c.792C>T p.H264= | Silent (SNP) | VAF 64/232 reads (28%) | catalogued as COSV54048057; called by muse, mutect2, varscan2
- CRYBG3 | c.8262C>A p.I2754= | Silent (SNP) | VAF 98/302 reads (32%) | catalogued as COSV51714964; called by muse, mutect2, varscan2
- DCHS2 | c.850C>T p.L284= | Silent (SNP) | VAF 219/730 reads (30%) | called by muse, mutect2, varscan2
- ESX1 | c.1083G>A p.P361= | Silent (SNP) | VAF 70/370 reads (19%) | catalogued as rs781810749, COSV65424091; called by muse, varscan2
- FAM170B | c.142C>A p.R48= | Silent (SNP) | VAF 122/422 reads (29%) | called by muse, mutect2, varscan2
- FBXL6 | c.1185G>A p.A395= | Silent (SNP) | VAF 177/883 reads (20%) | catalogued as rs782288913, COSV57352518; called by muse, mutect2, varscan2
- FLNB | c.6708C>T p.A2236= | Silent (SNP) | VAF 121/435 reads (28%) | catalogued as rs532347120; called by muse, mutect2, varscan2
- GOLGA4 | c.5554T>C p.L1852= | Silent (SNP) | VAF 79/286 reads (28%) | called by muse, mutect2, varscan2
- GRIK2 | c.2511G>T p.V837= | Silent (SNP) | VAF 112/350 reads (32%) | catalogued as rs1202805919; called by muse, mutect2, varscan2
- H2AC4 | c.126G>A p.E42= | Silent (SNP) | VAF 125/365 reads (34%) | catalogued as COSV52519191; called by muse, mutect2, varscan2
- HECW1 | c.321C>T p.D107= | Silent (SNP) | VAF 174/542 reads (32%) | catalogued as rs375404889; called by muse, mutect2, varscan2
- HOXD4 | c.60C>T p.C20= | Silent (SNP) | VAF 275/656 reads (42%) | catalogued as COSV60460167; called by muse, mutect2, varscan2
- IFT140 | c.3780G>T p.R1260= | Silent (SNP) | VAF 138/619 reads (22%) | catalogued as COSV100794315; called by muse, mutect2, varscan2
- LCOR | c.2409G>A p.K803= | Silent (SNP) | VAF 80/286 reads (28%) | called by muse, mutect2, varscan2
- LYST | c.5913G>A p.Q1971= | Silent (SNP) | VAF 97/188 reads (52%) | catalogued as COSV101089949; called by muse, mutect2, varscan2
- MMP21 | c.228G>A p.P76= | Silent (SNP) | VAF 185/686 reads (27%) | catalogued as COSV64290555; called by muse, mutect2, varscan2
- MUC16 | c.36615C>A p.T12205= | Silent (SNP) | VAF 42/175 reads (24%) | called by muse, mutect2, varscan2
- NDFIP2 | c.618A>G p.Q206= | Silent (SNP) | VAF 49/182 reads (27%) | called by muse, mutect2, varscan2
- NUMA1 | c.1617C>G p.L539= | Silent (SNP) | VAF 159/706 reads (23%) | called by muse, mutect2, varscan2
- OR14A2 | c.216G>A p.V72= | Silent (SNP) | VAF 61/266 reads (23%) | called by muse, mutect2, varscan2
- OR5P3 | c.795C>T p.S265= | Silent (SNP) | VAF 112/807 reads (14%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2520G>A p.P840= (on ENST00000393925 / NM_001134439.2; = p.P797= on NM_145753.2) | Silent (SNP) | VAF 190/314 reads (61%) | catalogued as rs369065786; called by muse, mutect2, varscan2
- PRKAR2A | c.843C>T p.I281= | Silent (SNP) | VAF 57/223 reads (26%) | catalogued as COSV55551961; called by muse, mutect2, varscan2
- RAD9A | c.456G>T p.L152= | Silent (SNP) | VAF 525/605 reads (87%) | called by muse, mutect2, varscan2
- RALGAPB | c.3993T>A p.G1331= | Silent (SNP) | VAF 92/914 reads (10%) | called by muse, mutect2, varscan2
- SLC8A2 | c.108C>T p.S36= | Silent (SNP) | VAF 109/490 reads (22%) | catalogued as rs749254915; called by muse, mutect2, varscan2
- SPSB2 | c.168C>T p.N56= | Silent (SNP) | VAF 182/518 reads (35%) | called by muse, mutect2, varscan2
- SSTR4 | c.987C>T p.R329= | Silent (SNP) | VAF 48/1684 reads (3%) | called by muse, mutect2
- ST6GAL1 | c.384G>T p.G128= | Silent (SNP) | VAF 139/599 reads (23%) | catalogued as rs776114800; called by muse, mutect2, varscan2
- TENM4 | c.1941C>T p.I647= | Silent (SNP) | VAF 168/1950 reads (9%) | called by muse, mutect2
- TMEFF2 | c.27G>A p.Q9= | Silent (SNP) | VAF 141/567 reads (25%) | catalogued as COSV55835112; called by muse, mutect2, varscan2
- TMPRSS12 | c.870C>T p.Y290= | Silent (SNP) | VAF 153/275 reads (56%) | catalogued as rs767272191, COSV68256858; called by muse, mutect2, varscan2
- TRAIP | c.1251C>T p.F417= | Silent (SNP) | VAF 119/396 reads (30%) | catalogued as rs1048291774, COSV58913861; called by muse, mutect2, varscan2
- WDPCP | c.1179A>T p.L393= | Silent (SNP) | VAF 32/382 reads (8%) | called by muse, mutect2
- ZNF595 | c.345A>G p.K115= | Silent (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- ZNF726 | c.1746G>A p.T582= | Silent (SNP) | VAF 53/275 reads (19%) | catalogued as rs373438470, COSV100484590; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3748G>T | Intron (SNP) | VAF 96/347 reads (28%) | catalogued as rs766988794; called by muse, mutect2, varscan2
- FRMD3 | c.1196-18577T>A | Intron (SNP) | VAF 140/478 reads (29%) | called by muse, mutect2, varscan2
- ZNF772 | chr19:57467076 G>T | 3'Flank (SNP) | VAF 161/284 reads (57%) | called by muse, mutect2, varscan2
